Somatic mutation profile of tumor specimen TCGA-Q1-A5R2-01A (aliquot TCGA-Q1-A5R2-01A-11D-A28B-09) from TCGA case TCGA-Q1-A5R2, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G3; Age at diagnosis: 64.4 years (23,523 days).
Specimen TCGA-Q1-A5R2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a977050-c281-46b3-b03d-388d6792c407.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Q1-A5R2-10A (Blood Derived Normal), aliquot TCGA-Q1-A5R2-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0ae923e-8a5f-4ab3-becc-488709cbf5a7

The open-access MAF lists 411 somatic variants for this specimen: 290 protein-altering or splice-affecting, 111 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 254, Silent 111, Nonsense Mutation 29, RNA 4, Intron 3, Splice Region 3, 3'UTR 2, In Frame Del 1, Nonstop Mutation 1, Frame Shift Del 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 9/115 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101229325, COSV67960197; called by muse, mutect2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 13/181 reads (7%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ADAM32 | c.1115C>G p.S372* | Nonsense Mutation (SNP) | VAF 3/41 reads (7%) | catalogued as COSV101165513; called by muse, mutect2
- ADCY8 | c.2331G>C p.W777C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53924146; called by muse, mutect2, varscan2
- ADGRA3 | c.2542C>T p.R848* | Nonsense Mutation (SNP) | VAF 5/93 reads (5%) | catalogued as COSV99293831; called by muse, mutect2
- ADGRB3 | c.3028G>A p.D1010N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV53257934; called by muse, mutect2, varscan2
- ADGRV1 | c.9747G>A p.M3249I | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV67993908; called by muse, mutect2, varscan2
- AGPAT3 | c.397G>A p.G133S | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52374280; called by muse, mutect2
- AHNAK2 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV60928427; called by muse, mutect2
- AK7 | c.1615C>A p.P539T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50881110, COSV50883110, COSV99966943; called by mutect2, varscan2
- AL136295.1 | c.2035G>C p.G679R | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357299018, COSV55781680; called by muse, mutect2, varscan2
- ALDH1A1 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.576); catalogued as COSV52792563; called by muse, mutect2, varscan2
- ALG10 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | catalogued as COSV99848381; called by muse, mutect2
- ANKAR | c.2654C>G p.S885C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV55617365, COSV99029171; called by muse, mutect2, varscan2
- AP1AR | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs562537794, COSV56770198; called by muse, mutect2, varscan2
- ARFGEF2 | c.2998G>A p.E1000K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100904129, COSV64214757; called by muse, mutect2, varscan2
- ARHGAP31 | c.2411C>T p.P804L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs760373610, COSV51798106, COSV99956814; called by muse, mutect2, varscan2
- ARMC4 | c.680C>G p.S227* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as COSV53467630, COSV53468017; called by muse, mutect2
- ARSI | c.1709G>C p.*570Sext*43 | Nonstop Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100156147; called by muse, mutect2
- ATG2B | c.4006G>C p.E1336Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55889603; called by muse, mutect2, varscan2
- ATG9A | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1041538685, COSV54699654; called by muse, mutect2
- BCAN | c.2653G>A p.D885N | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.006); catalogued as rs1438314281, COSV100228535, COSV61255604; called by muse, mutect2, varscan2
- BICD2 | c.2354C>T p.A785V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63550025, COSV63550697; called by muse, mutect2, varscan2
- BMPER | c.1612C>T p.Q538* | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV51829469; called by muse, mutect2, varscan2
- C1orf122 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); catalogued as COSV65990366; called by muse, mutect2, varscan2
- C1orf159 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.235); catalogued as rs1337617568, COSV53883252; called by muse, mutect2, varscan2
- C2orf42 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100034208; called by muse, mutect2
- C2orf68 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.933); catalogued as rs1260771594, COSV60383346; called by muse, mutect2
- CAMSAP1 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV100410482; called by muse, mutect2
- CAPS | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs199545548, COSV50385751, COSV99222348; called by muse, mutect2, varscan2
- CCDC112 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101100434; called by muse, mutect2
- CCDC180 | c.2179G>C p.D727H | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100827378; called by muse, mutect2
- CD27 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV56948500; called by muse, mutect2, varscan2
- CDH12 | c.2200G>A p.D734N | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1215841850, COSV66397885; called by muse, mutect2
- CFAP65 | c.4890C>G p.F1630L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs748555098, COSV58565727; called by muse, mutect2, varscan2
- CFAP77 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.021); catalogued as COSV58007417, COSV58016233; called by muse, mutect2, varscan2
- CHD7 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.483); catalogued as COSV101418070, COSV71113973; called by muse, mutect2, varscan2
- CHRM3 | c.249C>G p.I83M | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55091099, COSV55101463; called by muse, mutect2, varscan2
- CHRM3 | c.1622C>A p.P541H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55078511, COSV55085928; called by muse, mutect2, varscan2
- CHST4 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV100632968; called by muse, mutect2
- CLIC4 | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.151); catalogued as COSV100978224; called by muse, mutect2, varscan2
- CLSTN1 | c.2237A>G p.K746R (on ENST00000377298 / NM_001009566.3; = p.K736R on NM_014944.4) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs771283334, COSV63650638; called by muse, varscan2
- CNTF | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV60161495; called by muse, mutect2, varscan2
- CNTNAP2 | c.2555-1G>A p.X852_splice | Splice Site (SNP) | VAF 5/25 reads (20%) | catalogued as COSV62245041; called by muse, mutect2, varscan2
- COL6A3 | c.5138G>A p.G1713E | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779425587, COSV55106140; called by muse, mutect2, varscan2
- CPD | c.1915G>C p.D639H | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99853337; called by muse, mutect2
- CPNE6 | c.1054G>C p.D352H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53746172; called by muse, mutect2, varscan2
- CSPP1 | c.3400C>T p.R1134W (on ENST00000676605; = p.R1093W on NM_024790.6) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759630451, COSV51591631; called by muse, mutect2, varscan2
- CUBN | c.5603G>A p.W1868* | Nonsense Mutation (SNP) | VAF 19/71 reads (27%) | catalogued as COSV64725359; called by muse, mutect2, varscan2
- CYB5R2 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV55087207; called by muse, mutect2, varscan2
- DAG1 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs752984606, COSV58186785; called by muse, mutect2, varscan2
- DCDC2B | c.916G>C p.D306H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as COSV59085561; called by muse, varscan2
- DDX11 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.985); catalogued as COSV52509969; called by muse, varscan2
- DESI2 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.062); catalogued as rs1558139888, COSV55642839; called by muse, mutect2
- DIDO1 | c.4996G>A p.G1666S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV56632819; called by muse, mutect2
- DIP2A | c.3466G>A p.V1156M | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59485746; called by muse, mutect2, varscan2
- DNAH10 | c.955C>T p.Q319* (on ENST00000409039; = p.Q258* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV68988291; called by muse, mutect2, varscan2
- DNAJB5 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as rs202119401; called by muse, mutect2, varscan2
- DOCK4 | c.3083C>T p.S1028F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV70242438; called by muse, mutect2
- DST | c.7352C>G p.S2451* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | catalogued as COSV55036252; called by muse, mutect2, varscan2
- DTNA | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52022842; called by mutect2, varscan2
- DYNLL1 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs11544060, COSV54360019; called by muse, mutect2, varscan2
- DZIP3 | c.1906G>T p.D636Y | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.311); catalogued as COSV64313600, COSV64314268; called by muse, mutect2, varscan2
- E2F1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55776363; called by muse, mutect2
- ECI2 | c.511G>C p.E171Q (on ENST00000380118 / NM_206836.3; = p.E141Q on NM_006117.2) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.495); catalogued as COSV60986370, COSV60988714; called by muse, mutect2, varscan2
- ECM1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV60874855; called by muse, mutect2, varscan2
- EEF2K | c.238C>T p.H80Y | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0.057); catalogued as rs749406749, COSV53786250; called by muse, mutect2, varscan2
- EEPD1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs1019797143, COSV54200554; called by muse, mutect2, varscan2
- EIF3E | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99623599; called by muse, mutect2
- EIF4B | c.1385C>G p.S462C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as COSV50406899; called by muse, mutect2
- EPB41L3 | c.3175G>C p.E1059Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100550319, COSV59465601; called by muse, mutect2, varscan2
- EZHIP | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1557318803, COSV57957447; called by muse, mutect2, varscan2
- FAT1 | c.4321C>T p.Q1441* | Nonsense Mutation (SNP) | VAF 5/84 reads (6%) | catalogued as COSV71674653; called by muse, mutect2
- FBXL3 | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100842402; called by muse, mutect2
- FBXO42 | c.1354G>C p.G452R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV65046710; called by muse, mutect2, varscan2
- FEZ1 | c.468C>G p.I156M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs770703429, COSV54031428; called by muse, mutect2, varscan2
- FLII | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.03); catalogued as rs771487713, COSV58947705; called by muse, mutect2, varscan2
- FRMPD2 | c.2460C>G p.I820M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV59722883; called by muse, mutect2, varscan2
- GAK | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58508846; called by muse, mutect2, varscan2
- GALK1 | c.236C>G p.S79C | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as CM124972, CM124973, COSV56690452, COSV56692729; called by muse, mutect2
- GALM | c.158C>G p.S53W | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV55373700; called by muse, mutect2, varscan2
- GAS2 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV53411931; called by muse, mutect2, varscan2
- GFUS | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99643706; called by muse, mutect2
- GIPR | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV54426083; called by muse, mutect2
- GNAT3 | c.1062C>G p.F354L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.999); catalogued as COSV68069946; called by muse, mutect2, varscan2
- GPR173 | c.574A>T p.M192L | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as COSV100212139, COSV100212439; called by muse, mutect2
- HAS1 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV55789466; called by muse, mutect2
- HAUS2 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV53001052; called by muse, mutect2, varscan2
- HAUS7 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV57850893; called by muse, varscan2
- HCFC2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57557918, COSV57560202; called by muse, mutect2, varscan2
- HCN4 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs998387579, COSV56086816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDLBP | c.3343G>A p.D1115N | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV100191981; called by muse, mutect2, varscan2
- HELLS | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53298487; called by muse, mutect2, varscan2
- HELZ | c.3100C>G p.L1034V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62380584; called by muse, mutect2, varscan2
- HERC1 | c.11782G>A p.E3928K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0.037); catalogued as COSV71249898; called by muse, mutect2, varscan2
- HIF1AN | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV54501853; called by muse, mutect2, varscan2
- HMGN5 | c.125C>G p.S42* | Nonsense Mutation (SNP) | VAF 17/213 reads (8%) | catalogued as COSV100815034, COSV63916492; called by muse, mutect2
- IFT140 | c.3228G>C p.E1076D | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV54154470; called by muse, mutect2, varscan2
- IGF2BP1 | c.1320G>C p.K440N | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51735299; called by muse, mutect2, varscan2
- IGFLR1 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.241); catalogued as COSV53076385; called by muse, mutect2, varscan2
- IL15 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV56727796; called by muse, mutect2, varscan2
- IL17C | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs368594752, COSV54918159; called by muse, mutect2, varscan2
- IL1RAP | c.614C>G p.S205* | Nonsense Mutation (SNP) | VAF 4/60 reads (7%) | catalogued as COSV50768821; called by muse, mutect2
- IL1RAPL1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV100150966; called by muse, mutect2
- INPP5F | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as COSV100740430; called by muse, mutect2
- INTS1 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV67179428; called by muse, mutect2
- INTS12 | c.917C>G p.S306* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV60863431; called by muse, mutect2, varscan2
- IP6K1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57696532; called by muse, mutect2, varscan2
- ITGA4 | c.3046G>C p.E1016Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.131); catalogued as COSV59212862; called by muse, mutect2, varscan2
- ITPRID2 | c.340G>C p.D114H | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100238801; called by muse, mutect2
- JAG2 | c.3017G>A p.R1006Q | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs745934867, COSV100078633, COSV59312551; called by muse, mutect2
- JARID2 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV59196786; called by muse, mutect2, varscan2
- JCAD | c.1912A>T p.T638S | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs376187574; called by muse, mutect2
- JPH2 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60697935; called by muse, mutect2, varscan2
- KATNIP | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55190324; called by mutect2, varscan2
- KCTD10 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.145); catalogued as COSV99949469; called by muse, mutect2
- KIF23 | c.1662G>C p.Q554H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as COSV52982516; called by muse, mutect2
- KMT2C | c.9934C>T p.Q3312* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV51289396; called by muse, mutect2, varscan2
- KMT2D | c.14905G>T p.E4969* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as COSV56480095, COSV56501373; called by muse, mutect2, varscan2
- KMT2D | c.7297G>T p.E2433* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as CD1312974, COSV56459649; called by muse, mutect2, varscan2
- KMT2D | c.5362G>A p.A1788T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.638); catalogued as rs755651886, COSV56460703; called by muse, mutect2, varscan2
- L2HGDH | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.168); catalogued as rs75821386, COSV99910107; called by muse, mutect2
- LATS1 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV53598599; called by muse, mutect2, varscan2
- LCT | c.5569G>A p.G1857R | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.035); catalogued as rs763860055, COSV51556477; called by mutect2, varscan2
- LGR5 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as rs144739516, COSV99878000; called by muse, mutect2, varscan2
- LILRA5 | c.461C>A p.S154* | Nonsense Mutation (SNP) | VAF 16/128 reads (13%) | catalogued as COSV56644935; called by muse, mutect2, varscan2
- LIMCH1 | c.2560A>G p.T854A | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV58294885; called by muse, mutect2
- LPIN2 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs532359167, COSV55243599, COSV55245634; called by muse, mutect2, varscan2
- LRP1B | c.3775G>A p.E1259K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.824); catalogued as COSV67252475, COSV67266690; called by mutect2, varscan2
- LRP2 | c.6400C>G p.L2134V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV55570671; called by muse, mutect2, varscan2
- MAP4K4 | c.2182G>A p.E728K (on ENST00000347699 / NM_001242559.2; = p.E643K on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.391); catalogued as COSV56339523; called by muse, mutect2, varscan2
- MAP7D2 | c.165G>C p.Q55H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65529793; called by muse, mutect2
- MBD6 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.644); catalogued as rs371668485; called by muse, mutect2
- MED28 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs911090547, COSV99403863; called by muse, mutect2
- METTL3 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV52971007; called by muse, mutect2, varscan2
- MMEL1 | c.2299G>A p.G767S | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.838); catalogued as rs778580610, COSV99984565; called by muse, mutect2
- MPHOSPH10 | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV54916390; called by muse, mutect2, varscan2
- MTFR1 | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.729); catalogued as rs1045523269, COSV50952921; called by muse, mutect2, varscan2
- MTMR3 | c.1819C>T p.R607W | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs976261829, COSV60308201; called by muse, mutect2, varscan2
- MTMR4 | c.1225G>C p.D409H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60203190; called by muse, mutect2, varscan2
- MVP | c.2641C>G p.Q881E | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV62423283; called by muse, mutect2, varscan2
- MYH7 | c.5197G>A p.D1733N | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62523122; called by muse, mutect2, varscan2
- NAA25 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.08); catalogued as COSV55708369; called by muse, mutect2, varscan2
- NALCN | c.5054C>T p.S1685L | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99218174; called by muse, mutect2
- NBEAL1 | c.7678G>A p.E2560K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.967); catalogued as COSV68917137; called by muse, mutect2, varscan2
- NCBP1 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.102); catalogued as COSV64317412; called by muse, mutect2
- NCOR2 | c.1638C>G p.L546= | Splice Region (SNP) | VAF 11/73 reads (15%) | catalogued as COSV62303316; called by muse, mutect2, varscan2
- NEDD9 | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as rs1382064086, COSV65223508; called by muse, mutect2
- NFIB | c.1214C>G p.S405C | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.403); catalogued as COSV101101465; called by muse, mutect2
- NHLRC3 | c.558G>C p.L186F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV61489338; called by muse, mutect2, varscan2
- NINJ1 | c.93G>A p.W31* | Nonsense Mutation (SNP) | VAF 3/38 reads (8%) | catalogued as COSV100966631; called by muse, mutect2
- NKTR | c.4310G>C p.R1437T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV51774804; called by muse, mutect2, varscan2
- NLGN2 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV100081314; called by muse, mutect2
- NOTCH1 | c.3203G>A p.C1068Y | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53087588; called by muse, mutect2, varscan2
- NOTCH4 | c.2803G>A p.E935K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.245); catalogued as COSV66683453; called by muse, mutect2, varscan2
- NRARP | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV63083082; called by muse, varscan2
- NUBPL | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV55273978; called by muse, mutect2, varscan2
- OBSCN | c.16643C>T p.S5548L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751293477, COSV52760925; called by muse, mutect2, varscan2
- OSBPL1A | c.1381C>G p.L461V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs1567967767, COSV100111457, COSV60203155; called by muse, mutect2, varscan2
- OTUB1 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | catalogued as COSV100034417; called by muse, mutect2
- P3H3 | c.1199G>C p.S400T | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV51836086; called by muse, mutect2
- PA2G4 | c.695C>G p.S232* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV57570359; called by muse, mutect2, varscan2
- PAK2 | c.1107C>G p.I369M | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100505881, COSV100506399; called by muse, mutect2
- PAN2 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as COSV57755760; called by muse, mutect2, varscan2
- PARD3 | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs566752362, COSV60757269; called by muse, mutect2, varscan2
- PARP14 | c.5290C>G p.Q1764E | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs766000674, COSV101506364; called by muse, mutect2
- PCDH15 | c.3661C>T p.Q1221* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV57381160; called by muse, mutect2, varscan2
- PCDH19 | c.2688C>G p.F896L (on ENST00000373034 / NM_001184880.2; = p.F848L on NM_020766.3) | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV55270226; called by muse, mutect2, varscan2
- PCDHA13 | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.966); catalogued as rs1356283866, COSV56477666, COSV99170418; called by muse, mutect2
- PCDHGA2 | c.2356G>C p.E786Q | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); catalogued as COSV54018351; called by muse, mutect2, varscan2
- PCSK5 | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV70452345; called by muse, mutect2, varscan2
- PDE11A | c.1630C>G p.Q544E | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as COSV53706506; called by muse, mutect2
- PDE6D | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV55021182, COSV99808066; called by muse, mutect2, varscan2
- PDHA1 | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV100870309; called by muse, mutect2
- PEG3 | c.4236A>C p.E1412D | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV55625532, COSV55636235; called by muse, mutect2, varscan2
- PHLPP1 | c.2437G>T p.D813Y | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53023953; called by muse, mutect2, varscan2
- PIN1 | c.416T>C p.F139S | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53433161; called by muse, mutect2, varscan2
- PLEKHG4B | c.1666G>T p.A556S (on ENST00000283426; = p.A912S on NM_052909.5) | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as COSV52044030, COSV99361221; called by muse, mutect2
- POLRMT | c.3031G>C p.E1011Q | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV52114556, COSV99242375; called by muse, mutect2
- POT1 | c.1430G>A p.R477K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV62930355, COSV62934021; called by muse, mutect2, varscan2
- PPFIA2 | c.2120C>T p.S707F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV61028577; called by muse, mutect2, varscan2
- PPP1R12B | c.2281G>C p.E761Q | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.255); catalogued as COSV99295374; called by muse, mutect2
- PPP1R15A | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV52340177; called by muse, mutect2, varscan2
- PPP5C | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 5/81 reads (6%) | catalogued as COSV50140445, COSV99183545; called by muse, mutect2
- PRADC1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.042); catalogued as rs759178907, COSV57819577; called by mutect2, varscan2
- PRB1 | c.227A>T p.K76M | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV53706329; called by muse, mutect2, varscan2
- PREX1 | c.3739G>C p.E1247Q | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.049); catalogued as COSV64256058; called by muse, mutect2, varscan2
- PRPF38B | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100898348; called by muse, mutect2
- PSG8 | c.732C>G p.I244M | Missense Mutation (SNP) | VAF 18/239 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100126671; called by muse, mutect2
- PSMD2 | c.2158G>C p.E720Q | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); catalogued as COSV100032028; called by muse, mutect2
- PTPN5 | c.1656G>C p.M552I | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV60038095; called by muse, mutect2, varscan2
- PYDC2 | c.181A>G p.S61G | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.281); catalogued as COSV101573372; called by muse, mutect2
- QRFPR | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs781644429, COSV57679840; called by muse, mutect2, varscan2
- RALBP1 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV50038498; called by muse, mutect2, varscan2
- RALGAPA2 | c.2177G>A p.R726K | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as COSV99175159; called by muse, mutect2
- RALGDS | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs374152758; called by muse, mutect2, varscan2
- RANBP2 | c.3104C>G p.S1035* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV51699352; called by muse, mutect2
- RASAL3 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV59141376; called by muse, mutect2
- RDH13 | c.491C>T p.S164L (on ENST00000415061 / NM_001145971.2; = p.S93L on NM_138412.4) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV52560258, COSV52562625; called by muse, mutect2, varscan2
- RGS14 | c.1567G>C p.E523Q | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68771906; called by muse, mutect2, varscan2
- RND3 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs747141041, COSV55723389; called by mutect2, varscan2
- RNF19A | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.037); catalogued as COSV61993609; called by muse, mutect2, varscan2
- RRNAD1 | c.1015C>G p.H339D | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV63929349, COSV63929383; called by muse, mutect2, varscan2
- RSPRY1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV68028482; called by muse, mutect2, varscan2
- RUNX1T1 | c.334C>T p.Q112* (on ENST00000265814 / NM_001198628.1; = p.Q85* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/79 reads (18%) | catalogued as COSV56147272; called by muse, mutect2, varscan2
- RYR2 | c.2471A>G p.E824G | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100773176; called by muse, mutect2
- S1PR3 | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV100822648; called by muse, mutect2
- SAXO2 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.209); catalogued as COSV59755161; called by muse, mutect2, varscan2
- SCARF2 | c.2087C>A p.A696E | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.796); catalogued as COSV56731092, COSV99839492; called by muse, mutect2
- SCN9A | c.5174C>T p.S1725L (on ENST00000303354; = p.S1714L on NM_002977.3) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as COSV57604747; called by muse, mutect2, varscan2
- SCRN3 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55809567; called by muse, mutect2, varscan2
- SEMA6A | c.2233G>T p.A745S | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.999); catalogued as COSV56709658; called by muse, mutect2
- SH3KBP1 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV101116425; called by muse, mutect2
- SKOR1 | c.108G>A p.R36= | Splice Region (SNP) | VAF 3/34 reads (9%) | catalogued as COSV100408671; called by muse, mutect2
- SKOR1 | c.2413G>C p.D805H | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV100408673; called by muse, mutect2
- SLC12A9 | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV51936578; called by muse, mutect2, varscan2
- SLC2A8 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs748609075, COSV64895008; called by muse, mutect2, varscan2
- SLC35G2 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.259); catalogued as COSV101262113; called by muse, mutect2
- SLC35G2 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101262114; called by muse, mutect2
- SLC39A6 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV52371111; called by muse, mutect2, varscan2
- SLC6A13 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs142344531; called by muse, mutect2, varscan2
- SLC9A9 | c.1561G>C p.E521Q | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as COSV57242741; called by muse, mutect2, varscan2
- SLCO1C1 | c.551C>G p.S184C | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1220752923, COSV56878874; called by muse, mutect2, varscan2
- SLFN13 | c.1861C>T p.H621Y | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV99540464; called by muse, mutect2, varscan2
- SLIT2 | c.4360C>G p.R1454G | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs1195621837, COSV56589618, COSV56592032; called by muse, mutect2, varscan2
- SORL1 | c.6592G>C p.D2198H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV52761408; called by muse, mutect2
- SOS1 | c.3320C>T p.S1107F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV101217327; called by muse, mutect2
- SRPRA | c.1363G>C p.D455H | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55007977, COSV99703155; called by muse, mutect2
- STAG2 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1556521622, COSV54370813; ClinVar: uncertain significance; called by muse, mutect2
- STAG3 | c.1060G>C p.D354H | Missense Mutation (SNP) | VAF 13/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100426214; called by muse, mutect2
- SUMF2 | c.770C>T p.S257L (on ENST00000652303; = p.L286= on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs778778455, COSV51918663, COSV99305161; called by muse, mutect2, varscan2
- SYN3 | c.1345C>T p.Q449* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV60515167; called by muse, mutect2
- TCERG1 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.533); catalogued as COSV57041236; called by muse, mutect2
- TCF20 | c.1486G>C p.D496H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59495477; called by muse, mutect2, varscan2
- TECR | c.812C>A p.S271Y | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs1276260764, COSV99295288; called by muse, mutect2
- TENM4 | c.5086G>A p.E1696K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.104); catalogued as COSV53663927; called by muse, mutect2
- TET1 | c.2318C>T p.S773L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as COSV65386092; called by muse, mutect2, varscan2
- TET1 | c.3853C>G p.Q1285E | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV65388855; called by muse, mutect2, varscan2
- TG | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV55091773, COSV99603768; called by muse, mutect2, varscan2
- TMC4 | c.626C>T p.S209F (on ENST00000617472 / NM_001145303.3; = p.S203F on NM_144686.4) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1414814348, COSV55477392; called by muse, mutect2
- TMED8 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1415571458, COSV53627816; called by muse, mutect2, varscan2
- TNFRSF8 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs139967437; called by muse, mutect2, varscan2
- TNKS | c.2290G>C p.E764Q | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.373); catalogued as COSV100127972; called by muse, mutect2
- TOPBP1 | c.2698G>A p.E900K | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as rs1019705215, COSV53432640, COSV99605336; called by muse, mutect2
- TP53BP1 | c.851T>G p.L284R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99781674; called by muse, mutect2, varscan2
- TRIM45 | c.450C>A p.C150* | Nonsense Mutation (SNP) | VAF 9/87 reads (10%) | catalogued as rs1194820690, COSV99868784; called by muse, mutect2, varscan2
- TRPC4 | c.1156C>A p.H386N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100157423, COSV59015114; called by muse, mutect2, varscan2
- TSACC | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); catalogued as COSV55291128; called by muse, mutect2, varscan2
- TSEN54 | c.1300G>C p.D434H | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV99390606; called by muse, mutect2
- TSPEAR | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100555716; called by muse, mutect2
- TTC25 | c.1858G>C p.E620Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV66369091; called by mutect2, varscan2
- TTC3 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as rs556511744, COSV61295237; called by muse, varscan2
- TTC30B | c.739C>G p.Q247E | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68809362; called by muse, mutect2
- TTN | c.40207G>A p.E13403K (on ENST00000591111; = p.E5979K on NM_003319.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | PolyPhen probably damaging (0.994); catalogued as COSV60299445; called by muse, mutect2
- TXNRD1 | c.1308G>A p.T436= (on ENST00000525566 / NM_001093771.3; = p.T338= on NM_003330.4) | Splice Region (SNP) | VAF 4/17 reads (24%) | catalogued as rs771896901, COSV100723577, COSV61601215; called by mutect2, varscan2
- UBA5 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV99392739; called by muse, mutect2
- UGGT1 | c.3222G>C p.L1074F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1316624591, COSV99391280; called by muse, mutect2
- UHRF1 | c.1750G>A p.D584N (on ENST00000612630 / NM_001290050.1; = p.D597N on NM_013282.4) | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53576513; called by muse, mutect2, varscan2
- USH2A | c.2278A>G p.N760D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV56424648; called by muse, mutect2
- USP26 | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.168); catalogued as COSV63708412, COSV63708700; called by muse, mutect2, varscan2
- USP36 | c.2782G>A p.G928S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as rs780000218, COSV61751638; called by muse, mutect2, varscan2
- VAX2 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV52267160, COSV99313457; called by muse, mutect2, varscan2
- VGLL1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1333699985, COSV65703784; called by muse, mutect2
- WNT1 | c.194G>C p.S65T | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV53296793; called by muse, mutect2
- XKR4 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.047); catalogued as rs1344812255, COSV59336527; called by muse, mutect2, varscan2
- ZBTB6 | c.1014G>T p.K338N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV65410570; called by muse, mutect2, varscan2
- ZC3H12B | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100162115; called by muse, mutect2
- ZC3H13 | c.2217A>T p.R739S | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.966); catalogued as COSV54462093; called by muse, mutect2
- ZC3H6 | c.569C>G p.S190C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.706); catalogued as COSV59670251; called by muse, mutect2, varscan2
- ZFHX3 | c.4915A>G p.T1639A | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV51732950; called by muse, mutect2, varscan2
- ZFP36L2 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs763421001, COSV99144303; called by muse, mutect2
- ZIC3 | c.927C>G p.F309L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54973521, COSV54976525; called by muse, mutect2
- ZNF100 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.669); catalogued as COSV99974377; called by muse, mutect2
- ZNF134 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV68696812; called by muse, mutect2, varscan2
- ZNF251 | c.1725C>G p.F575L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV99478915; called by muse, mutect2
- ZNF28 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.121); catalogued as COSV60425084; called by muse, mutect2
- ZNF484 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as COSV60259405; called by muse, mutect2, varscan2
- ZNF564 | c.1122C>G p.F374L | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.744); catalogued as COSV100213320; called by muse, mutect2
- ZNF611 | c.101C>G p.S34* | Nonsense Mutation (SNP) | VAF 22/107 reads (21%) | catalogued as rs769173965, COSV60543074; called by muse, mutect2, varscan2
- ZNF665 | c.1105G>A p.E369K (on ENST00000600412; = p.E434K on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs1298164836, COSV67216702, COSV67217202; called by muse, mutect2, varscan2
- ZNF665 | c.662G>C p.G221A (on ENST00000600412; = p.G286A on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101128872; called by muse, mutect2
- ZNF711 | c.1876A>G p.K626E | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52156069, COSV99341679; called by muse, mutect2
- ZNF780A | c.1147C>T p.H383Y | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61816441; called by muse, mutect2, varscan2
- ZNF883 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.975); catalogued as rs756546653, COSV71308997; called by muse, mutect2, varscan2
- DMXL2 | c.3955G>C p.D1319H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2
- GATAD1 | c.666_672del p.C223Hfs*35 | Frame Shift Del (DEL) | VAF 30/75 reads (40%) | called by mutect2, pindel, varscan2
- MROH1 | c.2329C>G p.L777V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MUC2 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2
- TP73 | c.570_572del p.V191del | In Frame Del (DEL) | VAF 8/24 reads (33%) | called by pindel, varscan2
- TRPC4AP | c.591G>T p.L197F | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ACOT7 | c.345C>T p.P115= (on ENST00000377855 / NM_181864.3; = p.P105= on NM_007274.4) | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs11542480, COSV64115242; called by muse, mutect2, varscan2
- ANAPC1 | c.747C>G p.L249= | Silent (SNP) | VAF 5/103 reads (5%) | catalogued as COSV100595144; called by muse, mutect2
- ANKS1B | c.3603T>A p.L1201= (on ENST00000547776 / NM_152788.4; = p.L367= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/168 reads (18%) | catalogued as COSV100229115; called by muse, mutect2, varscan2
- ANXA2R | c.273C>T p.F91= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV59215262; called by muse, mutect2
- ASB17 | c.873G>A p.L291= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV52411846; called by muse, mutect2, varscan2
- ATAT1 | c.33C>T p.F11= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV99457956; called by muse, mutect2
- ATP6V0A2 | c.1206C>T p.I402= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV57751831; called by muse, mutect2, varscan2
- B3GNT9 | c.1095C>T p.H365= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV54627963; called by muse, mutect2, varscan2
- BICD2 | c.1176G>A p.E392= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV63547971, COSV63550706; called by muse, mutect2, varscan2
- CALR | c.63C>G p.V21= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV57135029; called by muse, mutect2, varscan2
- CASZ1 | c.2460C>T p.L820= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV59740406; called by muse, mutect2
- CCNJ | c.519G>A p.L173= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV56444306; called by muse, mutect2, varscan2
- CCT6B | c.1335C>G p.L445= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV58490935; called by muse, mutect2
- CELSR2 | c.2550C>G p.V850= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV54778607, COSV54779260; called by muse, mutect2, varscan2
- COL9A3 | c.1170C>T p.L390= | Silent (SNP) | VAF 9/111 reads (8%) | catalogued as rs770072884, COSV100673617; called by muse, mutect2
- CSNK1G2 | c.1113G>A p.L371= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV55339294; called by muse, mutect2, varscan2
- CYBB | c.1515G>A p.L505= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as CD106283, COSV66086183; called by muse, mutect2, varscan2
- CYFIP1 | c.2724C>T p.F908= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs145238748; called by muse, mutect2, varscan2
- DNLZ | c.261C>G p.S87= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV52518369; called by muse, mutect2, varscan2
- DOCK5 | c.2988G>C p.L996= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV52401001, COSV99378149; called by muse, mutect2, varscan2
- ENAH | c.468G>A p.L156= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs1380115276, COSV52872092; called by muse, mutect2, varscan2
- EPM2AIP1 | c.135C>T p.L45= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV99212825; called by muse, mutect2
- ERCC4 | c.2223C>G p.L741= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV61313797; called by muse, mutect2, varscan2
- F11 | c.75G>A p.L25= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV99251918; called by muse, mutect2
- FMO1 | c.705C>T p.F235= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV100707975; called by muse, mutect2
- FOXA2 | c.651C>T p.F217= (on ENST00000377115 / NM_153675.3; = p.F223= on NM_021784.5) | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV101008339, COSV65796015, COSV65797031; called by muse, mutect2, varscan2
- FZD4 | c.429G>C p.L143= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as COSV101536080; called by muse, mutect2
- FZD7 | c.1182C>T p.I394= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV99637497; called by muse, mutect2
- GABRE | c.426G>A p.L142= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as COSV64821872; called by muse, mutect2
- GATB | c.1206C>G p.V402= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs376818767, COSV99858883; called by muse, mutect2, varscan2
- GCC1 | c.2130C>T p.I710= | Silent (SNP) | VAF 33/143 reads (23%) | catalogued as COSV58462300, COSV58462572; called by muse, mutect2, varscan2
- GLTPD2 | c.366C>T p.F122= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV58702917; called by muse, mutect2, varscan2
- GOLGA6B | c.919C>T p.L307= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs1313384056, COSV69770562; called by muse, mutect2, varscan2
- GRIN1 | c.48C>T p.S16= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs201816843, COSV59300308; called by muse, mutect2
- GRIPAP1 | c.1014G>A p.L338= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100904401; called by muse, mutect2
- HOOK3 | c.897G>C p.L299= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV56887091; called by muse, mutect2, varscan2
- HSF2BP | c.792G>A p.L264= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV52359247; called by muse, mutect2, varscan2
- IGHE | c.642G>A p.P214= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs781897805; called by mutect2, varscan2
- IGHG4 | c.360C>G p.V120= | Silent (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- IRF4 | c.1122C>T p.H374= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs760994228, COSV66704965; called by mutect2, varscan2
- IRX1 | c.684C>T p.I228= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV57357956; called by muse, mutect2
- ITIH6 | c.3726G>C p.L1242= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV99514081; called by muse, mutect2
- KCNJ14 | c.291C>T p.F97= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV53520531; called by muse, mutect2, varscan2
- KIF18A | c.2493G>A p.R831= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV54187101; called by muse, mutect2, varscan2
- KLK11 | c.798G>T p.T266= (on ENST00000594768 / NM_144947.3; = p.T234= on NM_006853.3) | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100011320, COSV59399492; called by muse, mutect2, varscan2
- LGR6 | c.2337C>A p.I779= (on ENST00000367278 / NM_001017403.1; = p.I727= on NM_021636.3) | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV55165222; called by muse, mutect2, varscan2
- LILRB3 | c.75C>A p.P25= | Silent (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2, varscan2
- LIPH | c.1233C>G p.L411= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV56185692; called by muse, mutect2
- LPO | c.1161C>T p.L387= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV51861975; called by muse, mutect2, varscan2
- LRRK1 | c.5121C>T p.Y1707= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV99443567; called by muse, mutect2
- MRPS9 | c.72C>T p.L24= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV51521297; called by muse, mutect2, varscan2
- MYH4 | c.1539C>T p.F513= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV99702416; called by muse, mutect2
- MYO1H | c.2511C>T p.R837= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV60450108; called by muse, mutect2, varscan2
- NBAS | c.5556G>A p.Q1852= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV99871903; called by muse, mutect2
- NEURL1 | c.225C>T p.L75= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV63915469; called by muse, mutect2
- NLGN4X | c.1089C>G p.L363= | Silent (SNP) | VAF 18/144 reads (13%) | catalogued as COSV52033980; called by muse, mutect2, varscan2
- NODAL | c.699G>A p.K233= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs781458734, COSV54662465; called by muse, mutect2, varscan2
- NUAK2 | c.306G>A p.E102= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV65682518; called by muse, mutect2, varscan2
- NUP210 | c.3342C>T p.I1114= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV54412865; called by muse, mutect2, varscan2
- OBSCN | c.4866C>T p.P1622= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV52820974; called by muse, mutect2, varscan2
- OR10H4 | c.381C>T p.I127= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as COSV59062842; called by muse, varscan2
- OR5H14 | c.285T>A p.S95= | Silent (SNP) | VAF 6/178 reads (3%) | catalogued as COSV101454326; called by muse, mutect2
- OR6K6 | c.948C>T p.I316= (on ENST00000368144; = p.I292= on NM_001005184.1) | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV63743735; called by muse, mutect2, varscan2
- OSBPL7 | c.2091C>T p.V697= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV50114519; called by muse, mutect2, varscan2
- PALD1 | c.2442C>T p.Y814= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs769276686, COSV99698742; called by muse, mutect2, varscan2
- PAX3 | c.486C>T p.F162= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV51343478; called by muse, mutect2, varscan2
- PCDHB8 | c.1677G>A p.S559= | Silent (SNP) | VAF 30/571 reads (5%) | catalogued as rs782449653, COSV50754171; called by muse, mutect2
- PDE12 | c.24C>A p.R8= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV60819233; called by muse, mutect2, varscan2
- PDIA5 | c.1041C>T p.F347= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV60252023; called by muse, mutect2, varscan2
- PGAM2 | c.498C>T p.F166= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV51979473; called by muse, mutect2, varscan2
- PHF21A | c.414G>A p.L138= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV57659197; called by muse, mutect2, varscan2
- PIK3C2G | c.258G>A p.L86= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV56827114, COSV56829691; called by muse, mutect2, varscan2
- PIK3R2 | c.1131G>C p.L377= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV55850038; called by muse, mutect2, varscan2
- PLEKHG3 | c.1722G>A p.G574= (on ENST00000394691; = p.G630= on NM_001308147.2) | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV55983478; called by mutect2, varscan2
- PNMT | c.633C>T p.L211= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as COSV99510599, COSV99510832; called by muse, mutect2
- POTEE | c.402C>T p.H134= | Silent (SNP) | VAF 30/163 reads (18%) | catalogued as rs771263957, COSV58242039; called by muse, mutect2, varscan2
- PTK2B | c.2589C>T p.G863= | Silent (SNP) | VAF 7/83 reads (8%) | catalogued as rs1026723569, COSV57768218; called by muse, mutect2
- PTPN14 | c.1260C>T p.I420= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV100872979; called by muse, mutect2
- PTPRH | c.1977C>T p.L659= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV54749353; called by muse, mutect2, varscan2
- PXDNL | c.750C>T p.T250= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs372855537, COSV62499584; called by muse, mutect2, varscan2
- ROS1 | c.5355C>T p.I1785= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV63860752; called by muse, mutect2, varscan2
- SCAMP3 | c.807G>A p.P269= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs368184754; called by muse, mutect2
- SLC18A3 | c.1095T>G p.A365= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV60331941; called by muse, mutect2, varscan2
- SLC2A1 | c.576C>T p.I192= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs1166523269, COSV65288302; called by muse, mutect2, varscan2
- SLC36A4 | c.258T>C p.N86= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100419492; called by muse, mutect2, varscan2
- SLC66A2 | c.648C>T p.F216= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV100301897, COSV100302153; called by muse, mutect2
- SPATA31D1 | c.24G>A p.L8= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV61200479; called by muse, mutect2, varscan2
- STK11 | c.444C>T p.F148= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as rs1283208395, COSV100481121; called by muse, mutect2
- STK32A | c.393C>A p.V131= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV60422444; called by muse, mutect2, varscan2
- TBR1 | c.1101C>T p.I367= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV67419081; called by muse, mutect2, varscan2
- TBXAS1 | c.1431G>A p.R477= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV54945515; called by muse, mutect2, varscan2
- TEDC2 | c.1002G>A p.G334= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs780606469, COSV62523223; called by muse, mutect2, varscan2
- TEX14 | c.1335C>T p.I445= (on ENST00000240361 / NM_001201457.2; = p.I439= on NM_031272.5) | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV53624930; called by muse, mutect2, varscan2
- THEMIS2 | c.150C>T p.I50= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV61078359; called by muse, mutect2, varscan2
- THUMPD3 | c.1035C>T p.F345= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100560797; called by muse, mutect2, varscan2
- TNP1 | c.114G>C p.L38= | Silent (SNP) | VAF 4/57 reads (7%) | catalogued as COSV52696424, COSV99378655; called by muse, mutect2
- TNS4 | c.1602C>G p.L534= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV54187700; called by muse, mutect2, varscan2
- TPO | c.2655G>A p.S885= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs756050827, COSV61101520; called by muse, mutect2, varscan2
- TRIM38 | c.582G>A p.E194= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs764999606, COSV62642570, COSV62642831; called by muse, mutect2, varscan2
- TSPOAP1 | c.1407C>T p.V469= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV52116423; called by muse, mutect2, varscan2
- TTN | c.78057A>G p.L26019= (on ENST00000591111; = p.L18595= on NM_003319.4) | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs760972930, COSV60299410; called by muse, mutect2, varscan2
- TUBB2A | c.561C>T p.L187= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV61319471; called by muse, mutect2, varscan2
- UBC | c.2055C>G p.V685= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as rs750793705, COSV60061194; called by muse, mutect2, varscan2
- UBXN6 | c.69C>G p.L23= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs780500807, COSV56680240; called by muse, mutect2, varscan2
- UBXN8 | c.666G>A p.T222= | Silent (SNP) | VAF 5/102 reads (5%) | catalogued as rs1427226542; called by muse, mutect2
- USP35 | c.2499C>A p.L833= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV60870588; called by muse, mutect2, varscan2
- VEPH1 | c.652C>T p.L218= | Silent (SNP) | VAF 7/108 reads (6%) | catalogued as COSV100748100; called by muse, mutect2
- VWA3B | c.3759G>A p.A1253= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV71373562; called by muse, mutect2
- VWA8 | c.5049G>A p.K1683= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs1350468991, COSV64999820; called by muse, mutect2, varscan2
- ZDHHC13 | c.1626C>G p.L542= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV101240077, COSV67980914; called by muse, mutect2, varscan2
- ZNF419 | c.525C>T p.L175= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs770521026, COSV55662709; called by muse, mutect2, varscan2
- AC245047.1 | n.154G>T | RNA (SNP) | VAF 20/185 reads (11%) | called by muse, mutect2, varscan2
- C1orf122 | c.*92C>T | 3'UTR (SNP) | VAF 8/40 reads (20%) | catalogued as rs1291969496, COSV65990372; called by muse, varscan2
- DDX41 | c.*544G>A | 3'UTR (SNP) | VAF 9/41 reads (22%) | catalogued as COSV57254266; called by muse, mutect2, varscan2
- DOCK8 | chr9:214656 C>T | 5'Flank (SNP) | VAF 11/26 reads (42%) | catalogued as COSV66688426; called by muse, mutect2, varscan2
- HMGB1P1 | n.604G>A | RNA (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- MAP3K20 | c.987+4260G>T | Intron (SNP) | VAF 3/22 reads (14%) | catalogued as COSV59105956; called by muse, mutect2
- MIR19B2 | n.58T>G | RNA (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- PKD1L2 | n.1339C>T | RNA (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2
- RC3H2 | c.961-95G>C | Intron (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100106952, COSV59014913; called by muse, mutect2, varscan2
- SV2C | c.581-21184G>C | Intron (SNP) | VAF 16/79 reads (20%) | catalogued as COSV59227699; called by muse, mutect2, varscan2
